Gene-level copy-number profile of tumor specimen MP2PRT-PASWJK-TMP1-A from MP2PRT case MP2PRT-PASWJK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,267 days).
Specimen MP2PRT-PASWJK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5be83ffb-759d-48cc-9aa7-dc15742bd223.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASWJK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/66b9d002-4a64-4aa2-8a5a-a7c4972f4501

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 576; copy number 2: 29,419; copy number 3: 25,280; copy number 4: 3,621; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,439,346–64,440,180, 1 gene, copy number 5: SNX18P9.
- chr9:64,486,164–64,498,745, 3 genes, copy number 5: CNN2P3, GXYLT1P6, AL773524.1.

Autosomal genes at a single copy (total copy number 1): 64. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
